Somatic mutation profile of tumor specimen 55d3d4bb-0bf5-4b4e-8ef8-d77a5d (aliquot 55d3d4bb-0bf5-4b4e-8ef8-d77a5d_D6) from CPTAC case 05BR001, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 69.9 years (25,549 days).
Specimen 55d3d4bb-0bf5-4b4e-8ef8-d77a5d: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 25b20d3b-ae61-43f0-9620-4d44bd1043ea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 90128f2d-2a4c-4514-bcc8-e39be7 (Blood Derived Normal), aliquot 90128f2d-2a4c-4514-bcc8-e39be7_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a0c3d250-4559-4f0d-9a30-090e6b00f743

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- OR4Q3 | c.890C>A p.T297K | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
